Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3814, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3814-01A (Primary Tumor).

Tumor entity (in block A)

Colic adenocarcinoma with characteristic solid and ductal cell elements, with loss of cell nucleus polarity and increased chromatin image.

Invasion of around 1 cm with infiltration of the bordering fatty connective tissue (pT3)

Tumor classification (TNM, 6th edition)

Stage grouping

ICDO-DA M-8140/3

G2

pT3, pN0, MX, L1, V1

R0

Source: NCI Genomic Data Commons file ce5e7f83-db37-446a-b159-763bc7d7c6e5 (TCGA-AA-3814.8521E575-B0FE-42B3-BAAD-107A913A7C21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).